CCDI case PBCAYN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/c9558dd3-6d4c-4447-834c-fc42d2e12469

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 16.4 years (5,991 days).

Biospecimens (3 samples)
- Sample 0DN62Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DN636, 0DO7MD (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
